Somatic mutation profile of tumor specimen ALCH-B4XH-TTP1-A (aliquot ALCH-B4XH-TTP1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B4XH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.1 years (22,307 days).
Specimen ALCH-B4XH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07616d5b-13c9-4a6d-ad21-96980ae4fc75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4XH-NB1-A (Blood Derived Normal), aliquot ALCH-B4XH-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fb3fa00-d91d-462f-ada3-3fa4122fa7aa

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 55/576 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2
- TP53 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 14/178 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587782620, CM132087, COSV52665025, COSV53025766, COSV53135444, COSV53176166; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- CARD18 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs1468204154; called by muse, mutect2
- DNAH7 | c.6554G>A p.R2185H | Missense Mutation (SNP) | VAF 30/524 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754967966, COSV56763812; called by muse, mutect2
- KIAA1586 | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.357); catalogued as rs772471328; called by muse, mutect2, varscan2
- KRTAP16-1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 37/357 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1218299949; called by muse, mutect2, varscan2
- PINK1 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CD083340, CM1512552; called by muse, mutect2
- TIAM1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 14/460 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs970048985, COSV99732887; called by muse, mutect2
- DNAH7 | c.5797T>G p.L1933V | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.078); called by muse, varscan2
- DPP6 | c.1144T>A p.Y382N (on ENST00000377770 / NM_001364500.2; = p.Y320N on NM_001936.5) | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F13A1 | c.1707C>A p.F569L | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.14); called by muse, mutect2
- METTL15 | c.1100C>G p.S367C | Missense Mutation (SNP) | VAF 29/482 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.748); called by muse, mutect2
- SPTA1 | c.4073G>A p.S1358N | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.023); called by muse, mutect2
- SPTAN1 | c.5330A>G p.E1777G | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZBTB14 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 17/330 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2
- ZKSCAN5 | c.1953T>A p.H651Q | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATIC | c.423A>G p.R141= | Silent (SNP) | VAF 24/510 reads (5%) | called by muse, mutect2
- GIPR | c.1185C>A p.I395= | Silent (SNP) | VAF 13/386 reads (3%) | called by muse, mutect2
- NOTCH3 | c.6378C>T p.P2126= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs775029302, COSV54641506; called by muse, mutect2, varscan2
- NSFL1C | c.1065G>A p.L355= | Silent (SNP) | VAF 10/282 reads (4%) | called by muse, mutect2
- SEC24D | c.1779C>T p.L593= | Silent (SNP) | VAF 36/461 reads (8%) | called by muse, mutect2
- SLC9B1 | c.1350G>T p.L450= | Silent (SNP) | VAF 16/654 reads (2%) | called by muse, mutect2
- ZBTB47 | c.1572C>T p.I524= | Silent (SNP) | VAF 11/230 reads (5%) | called by muse, mutect2
- NACA | c.71-1496C>T | Intron (SNP) | VAF 18/372 reads (5%) | called by muse, mutect2
